CCDI case PBBUVW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fc26f661-c924-4887-9a28-a1063d2656ea

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,778 days).

Biospecimens (3 samples)
- Sample 0DHY30: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHY3W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHY4G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
